Somatic mutation profile of tumor specimen C3L-00581-02 (aliquot CPT0007330009) from CPTAC case C3L-00581, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 52.6 years (19,213 days).
Specimen C3L-00581-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6328f89b-a1eb-4e1f-a945-7710625a35fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00581-31 (Blood Derived Normal), aliquot CPT0002780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32c3f66d-6708-4d10-98bf-c82a3683d72a

The open-access MAF lists 106 somatic variants for this specimen: 73 protein-altering or splice-affecting, 18 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 18, Intron 9, Frame Shift Del 9, Frame Shift Ins 4, 5'UTR 3, Splice Site 3, RNA 1, In Frame Del 1, 3'UTR 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1416del p.S473Vfs*98 | Frame Shift Del (DEL) | VAF 38/171 reads (22%) | catalogued as rs1060503731; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADD2 | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV52459516; called by muse, mutect2, varscan2
- BICC1 | c.2445C>A p.N815K | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99570989; called by muse, varscan2
- CLPTM1L | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.295); catalogued as rs762247898; called by muse, mutect2, varscan2
- DNAH2 | c.4045G>T p.E1349* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV66727272; called by muse, mutect2, varscan2
- ERCC3 | c.2263G>C p.D755H | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV53425589; called by muse, mutect2, varscan2
- FLG2 | c.6790C>T p.H2264Y | Missense Mutation (SNP) | VAF 56/400 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs770971156; called by muse, mutect2, varscan2
- MYO3A | c.3576G>A p.M1192I | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56349084; called by muse, mutect2, varscan2
- SCGB3A2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs774802794; called by muse, mutect2, varscan2
- SFSWAP | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.498); catalogued as rs1170451411; called by muse, mutect2, varscan2
- SLC39A14 | c.434_436del p.E145del | In Frame Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs772125874; called by pindel, varscan2
- STEAP4 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1326771233; called by muse, mutect2, varscan2
- THEMIS | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs765387427, COSV100965532, COSV64070629; called by muse, mutect2, varscan2
- ZNF267 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV56256255; called by muse, mutect2, varscan2
- ZNF536 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 77/387 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62821960; called by muse, mutect2, varscan2
- A2ML1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- ANKRD26 | c.2171G>T p.S724I | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- AQR | c.3894A>C p.R1298S | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATXN2L | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- BPIFB6 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CBARP | c.2176T>G p.*726Eext*? | Nonstop Mutation (SNP) | VAF 9/59 reads (15%) | called by muse, varscan2
- CC2D1A | c.2074-2A>G p.X692_splice | Splice Site (SNP) | VAF 39/194 reads (20%) | called by muse, mutect2, varscan2
- CDH2 | c.439T>A p.F147I | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK10 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- COL7A1 | c.2142_2148del p.Y715Ffs*37 | Frame Shift Del (DEL) | VAF 54/324 reads (17%) | called by mutect2, pindel, varscan2
- CPNE5 | c.311C>G p.P104R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CSAG3 | c.65del p.K22Rfs*9 | Frame Shift Del (DEL) | VAF 27/132 reads (20%) | called by mutect2, varscan2
- CST7 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2
- CTBP1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- DKK4 | c.500A>T p.K167M | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.9739G>C p.D3247H | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- FOXB2 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- GSDMC | c.301A>C p.I101L | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPACAM2 | c.307C>A p.P103T (on ENST00000394468 / NM_001039372.4; = p.P91T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICAM5 | c.1847A>G p.E616G | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNA10 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- KLHL22 | c.261del p.E87Dfs*6 | Frame Shift Del (DEL) | VAF 19/95 reads (20%) | called by mutect2, pindel, varscan2
- KPNB1 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- LPIN1 | c.482dup p.S162Vfs*10 | Frame Shift Ins (INS) | VAF 56/304 reads (18%) | called by mutect2, pindel, varscan2
- LTBP1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- LY75 | c.1344T>G p.D448E | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- MCTP1 | c.2449del p.V817Lfs*9 | Frame Shift Del (DEL) | VAF 48/301 reads (16%) | called by mutect2, pindel, varscan2
- OR6C74 | c.332_333del p.F111Sfs*8 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB2 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); called by muse, mutect2
- PCMTD2 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PLEKHA6 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PRG4 | c.3497_3498insT p.G1167Rfs*21 | Frame Shift Ins (INS) | VAF 41/338 reads (12%) | called by mutect2, pindel*, varscan2*
- PRRC2C | c.8200-1G>A p.X2734_splice (on ENST00000367742; = p.X2732_splice on NM_015172.4) | Splice Site (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2
- RCBTB2 | c.103del p.S35Pfs*10 | Frame Shift Del (DEL) | VAF 15/134 reads (11%) | called by mutect2, pindel, varscan2
- RYR2 | c.2679G>C p.W893C | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA7A | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SH3GL1 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 106/554 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SMC1B | c.759A>C p.R253S | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SORL1 | c.4407del p.R1470Dfs*43 | Frame Shift Del (DEL) | VAF 42/269 reads (16%) | called by mutect2, pindel, varscan2
- SPP1 | c.404A>G p.D135G (on ENST00000395080 / NM_001040058.2; = p.D121G on NM_000582.2) | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STOML2 | c.218T>A p.I73N | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SYTL2 | c.584-2A>G p.X195_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- TNKS2 | c.910dup p.T304Nfs*8 | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- TONSL | c.4055T>C p.L1352P | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TTN | c.45527T>G p.I15176S (on ENST00000591111; = p.I7752S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- UFSP2 | c.727_728del p.F243Qfs*4 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- UHRF2 | c.1811T>G p.L604W | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VHL | c.413dup p.S139Ifs*5 | Frame Shift Ins (INS) | VAF 47/253 reads (19%) | called by mutect2, pindel, varscan2
- WNK1 | c.6272A>C p.Q2091P (on ENST00000315939 / NM_018979.4; = p.Q1843P on NM_014823.3) | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2
- XRN2 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZBTB48 | c.1459C>A p.H487N | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H12C | c.285T>A p.N95K | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP3 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZNF26 | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF33A | c.1774A>G p.K592E (on ENST00000458705 / NM_006974.3; = p.K593E on NM_006954.2) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ZNF568 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- ZNF583 | c.1362T>G p.H454Q | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZSCAN2 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARMC7 | c.462C>T p.A154= | Silent (SNP) | VAF 61/367 reads (17%) | called by muse, mutect2, varscan2
- BCR | c.1164C>T p.C388= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- GPR21 | c.1011A>G p.T337= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1431892578; called by muse, mutect2
- HOXB4 | c.57A>C p.P19= | Silent (SNP) | VAF 71/427 reads (17%) | catalogued as rs1205895976, COSV60177977; called by muse, mutect2, varscan2
- KCNQ1 | c.1866C>A p.G622= | Silent (SNP) | VAF 39/151 reads (26%) | called by muse, mutect2, varscan2
- KIF20A | c.546G>A p.R182= | Silent (SNP) | VAF 41/224 reads (18%) | catalogued as rs1483175198; called by muse, mutect2, varscan2
- LRRC8D | c.1662C>T p.A554= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs574691834; called by muse, mutect2, varscan2
- MLXIP | c.2530C>T p.L844= | Silent (SNP) | VAF 38/187 reads (20%) | called by muse, mutect2, varscan2
- PDIA5 | c.807T>C p.T269= | Silent (SNP) | VAF 31/134 reads (23%) | called by muse, mutect2, varscan2
- PKP3 | c.687G>T p.L229= | Silent (SNP) | VAF 86/410 reads (21%) | called by muse, mutect2, varscan2
- RSC1A1 | c.909T>C p.D303= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- SEC14L1 | c.2059C>T p.L687= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as rs377362452; called by muse, mutect2, varscan2
- SLC13A2 | c.153T>C p.T51= | Silent (SNP) | VAF 32/192 reads (17%) | called by muse, mutect2, varscan2
- STEAP4 | c.177C>A p.P59= | Silent (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- STOML2 | c.219C>A p.I73= | Silent (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.2478G>A p.A826= | Silent (SNP) | VAF 61/317 reads (19%) | catalogued as rs372465003; called by muse, mutect2, varscan2
- UHRF2 | c.1810T>C p.L604= | Silent (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2, varscan2
- VPS13D | c.4170G>A p.R1390= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1528A>C | RNA (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10087G>C | Intron (SNP) | VAF 71/479 reads (15%) | called by muse, mutect2, varscan2
- COPS7A | c.163-252_163-238del | Intron (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel
- EIF4G3 | c.299+11C>T | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, varscan2
- FOXM1 | c.1021-9C>G | Intron (SNP) | VAF 32/168 reads (19%) | called by muse, mutect2, varscan2
- GFI1 | c.-5C>T | 5'UTR (SNP) | VAF 67/393 reads (17%) | called by muse, mutect2, varscan2
- GJD4 | c.-29C>A | 5'UTR (SNP) | VAF 10/274 reads (4%) | catalogued as COSV100397206; called by muse, mutect2
- HADH | c.133-4891G>C | Intron (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- HMGN1 | chr21:39349475 C>G | 5'Flank (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.-11A>G | 5'UTR (SNP) | VAF 22/114 reads (19%) | catalogued as rs1208399434; called by muse, varscan2
- RGS11 | c.658-16A>T | Intron (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- SH3TC1 | c.481+609C>G | Intron (SNP) | VAF 42/204 reads (21%) | called by muse, mutect2, varscan2
- SYP | c.*4+24G>A | Intron (SNP) | VAF 16/168 reads (10%) | catalogued as rs782014669, CR121461; called by muse, mutect2
- WDR11 | c.*32G>A | 3'UTR (SNP) | VAF 57/254 reads (22%) | called by muse, mutect2, varscan2
- ZNF880 | c.269-4338T>C | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as rs1338089749; called by muse, mutect2
